Somatic mutation profile of tumor specimen TARGET-10-PATLNS-09A (aliquot TARGET-10-PATLNS-09A-01D) from TARGET case TARGET-10-PATLNS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (823 days).
Specimen TARGET-10-PATLNS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abfa3d99-e960-41f2-9e7a-cf67828aa7e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATLNS-10A (Blood Derived Normal), aliquot TARGET-10-PATLNS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34ede6cd-8948-4df5-ab5b-bc571c1cecb5

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, In Frame Ins 1, 3'UTR 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 61/72 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs756477540, COSV55882246, COSV99918704, COSV99925621; called by muse, mutect2, varscan2
- NOTCH1 | c.4787T>A p.L1596H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53039455; called by muse, mutect2
- NOTCH1 | c.4627_4628insTTC p.G1543delinsVR | In Frame Ins (INS) | VAF 9/30 reads (30%) | catalogued as COSV53084693; called by mutect2, pindel, varscan2
- NRCAM | c.2689C>T p.R897C (on ENST00000379028 / NM_001371124.1; = p.R881C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as COSV61049039; called by muse, mutect2
- RAB40C | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234126973, COSV50193732; called by muse, mutect2, varscan2
- ABCA2 | c.4008C>T p.S1336= (on ENST00000614293; = p.S1306= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/47 reads (55%) | called by muse, varscan2
- CTLA4 | c.468G>A p.P156= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs200657280; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHGA5 | c.585G>A p.V195= | Silent (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- RAB3IP | c.1263T>C p.P421= (on ENST00000550536 / NM_175623.4; = p.P405= on NM_022456.5) | Silent (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- C11orf16 | c.325-389C>T | Intron (SNP) | VAF 18/44 reads (41%) | catalogued as rs1007794913; called by muse, mutect2, varscan2
- SFTPA2 | c.*7T>G | 3'UTR (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- WHAMMP3 | chr15:22690738 C>T | 3'Flank (SNP) | VAF 35/92 reads (38%) | catalogued as rs1480063625; called by muse, mutect2, varscan2
